Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5502, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5502-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 5.3. The patient also has a history of biopsy [REDACTED] this biopsy reveals: Moderately differentiated adenocarcinoma, Gleason score 3+3 = 6 in the left and right sides of the prostate. [REDACTED] with prostate cancer.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

TCGA - EJ - 5502

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN THREE (3) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN EIGHT (8) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- C. THE CARCINOMA INVOLVES 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5.3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	10%
WEIGHT OF PROSTATE:	41.70gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	3
LYMPH NODES POSITIVE:	8
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file bf53b2c1-8d77-48f6-a88c-8507b216e220 (TCGA-EJ-5502.173E45E9-E2AB-4A1D-8BCC-15374F1AE511.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).